Gene-level copy-number profile of tumor specimen TCGA-85-6798-01A from TCGA case TCGA-85-6798, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 57.0 years (20,837 days).
Specimen TCGA-85-6798-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.5bbd4cca-6e55-417d-a28d-16b5eec9e759.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-6798-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/acbaa228-315d-4dae-bc0a-f50c323df54d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,650; copy number 2: 15,659; copy number 3: 20,438; copy number 4: 15,071; copy number 5: 2,119; copy number 6: 1,816; copy number 7: 1,360; copy number 8: 285; copy number 9: 35; copy number 10: 19; copy number 12: 2; copy number 13: 25; copy number 15: 77; copy number 17: 205; copy number 23: 52.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-6798-01A-11D-1943-01): tumor purity 0.47, ploidy 3.18, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,060 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:182,716,041–183,161,680, 12 genes, copy number 10 (within-gene range 6–10): DNAJC10, RPL31P15, Y_RNA, FRZB, RNU6-1122P, NCKAP1, Y_RNA, AC064871.1, KRT8P10, DUSP19, AC064871.2, NUP35.
- chr2:190,189,735–197,786,762, 98 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr2:197,817,423–197,836,326, 1 gene, copy number 7: AC011997.2.
- chr3:149,738,472–198,222,513, 863 genes, copy number 7–23 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 7 (broad region; genes not listed).
- chr6:49,430,360–60,546,660, 150 genes, copy number 7–12 (within-gene range 4–12) (broad region; genes not listed).
- chr6:134,283,092–134,520,585, 7 genes, copy number 8: Y_RNA, AL355881.1, KRT8P42, LINC01010, Z84486.1, CHCHD2P4, CT69.
- chr7:146,050,062–148,420,998, 10 genes, copy number 7 (within-gene range 5–7): AC073308.1, CNTNAP2, AC073418.1, Y_RNA, CNTNAP2-AS1, DUTP3, RANP2, MIR548F4, AC005518.1, AC005518.2.
- chr9:37,422,666–37,576,380, 8 genes, copy number 9 (within-gene range 2–9): GRHPR, CHCHD4P3, ZBTB5, KCTD9P3, POLR1E, AL158156.1, AL513165.1, FBXO10.
- chr13:104,814,327–114,337,626, 162 genes, copy number 7 (broad region; genes not listed).
- chr18:31,447,741–32,745,567, 39 genes, copy number 7 (within-gene range 2–7): DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7, AC025887.2, WBP11P1, AC009835.1, AC025887.1.

Autosomal genes at a single copy (total copy number 1): 829. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
